MMRF case MMRF_1792 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7cb64eb5-ea4a-4461-b140-c8906454a624

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 47 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 47.7 years (17,409 days); ISS stage: II; Days to last known disease status: 1,087 days (3.0 years); Days to last follow up: 1,087 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 57 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 58 days; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 118 days; Days to treatment end: 118 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 149 days; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 149 days; Days to treatment end: 197 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 163 days; Days to treatment end: 197 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 203 days; Days to treatment end: 205 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 206 days; Days to treatment end: 206 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 208 days; Days to treatment end: 208 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 301 days; Days to treatment end: 482 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 484 days (1.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 1): M Protein 4.86 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.23 mg/dL; Immunoglobulin G 54.3 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 4.9 µg/mL; Lactate Dehydrogenase 6.85 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 64 µmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 10.3 g/dL; Glucose 5 mmol/L.
- Day 79 (ECOG 1): M Protein 1.72 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 23.7 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.14 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 3.58 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 58 µmol/L; Calcium 2.11 mmol/L; Albumin 35 g/L; Total Protein 7.4 g/dL; Glucose 7 mmol/L.
- Day 177 (ECOG 1): M Protein 8.5 g/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 58 µmol/L; Calcium 2.14 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 5.5 mmol/L.
- Day 268 (ECOG 1): M Protein 2.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.51 mg/dL; Immunoglobulin G 6.3 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 61 µmol/L; Calcium 2.24 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 5.7 mmol/L.
- Day 359 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 8.9 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 3.87 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 61 µmol/L; Calcium 2.29 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.6 mmol/L.
- Day 443: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.73 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 3.83 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 66 µmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 7.3 g/dL; Glucose 6 mmol/L.
- Day 527 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.49 g/L; Lactate Dehydrogenase 5.85 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 61 µmol/L; Calcium 2.39 mmol/L; Albumin 44 g/L; Total Protein 7.4 g/dL; Glucose 5.3 mmol/L.
- Day 639 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.82 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 4.13 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 62 µmol/L; Calcium 2.17 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 4.8 mmol/L.
- Day 748 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 6.37 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 60 µmol/L; Calcium 2.16 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 6 mmol/L.
- Day 807 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.79 mg/dL; Immunoglobulin G 13.4 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.65 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 63 µmol/L; Calcium 2.26 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 5.1 mmol/L.
- Day 891 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 1.07 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.78 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 72 µmol/L; Calcium 2.26 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 6.5 mmol/L.
- Day 1,003 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 4.62 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 68 µmol/L; Calcium 2.37 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 6.1 mmol/L.
- Day 1,087 (ECOG 1): M Protein 4.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.83 mg/dL; Immunoglobulin G 16.7 g/L; Immunoglobulin A 0.99 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 4.77 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 61 µmol/L; Calcium 2.31 mmol/L; Albumin 40 g/L; Total Protein 7.3 g/dL; Glucose 5.9 mmol/L.

Other clinical attributes
- Day 0: Weight: 80 kg; Height: 156 cm.

Biospecimens (2 samples)
- Sample MMRF_1792_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1792_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
